Somatic mutation profile of tumor specimen TCGA-36-2540-01A (aliquot TCGA-36-2540-01A-01D-1526-09) from TCGA case TCGA-36-2540, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G1; Age at diagnosis: 26.7 years (9,760 days).
Specimen TCGA-36-2540-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75a49e67-6c9e-4400-8f6c-ef588c55023f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-36-2540-10A (Blood Derived Normal), aliquot TCGA-36-2540-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb0b5b87-ab63-424e-9c6b-75650b095e18

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRWD1 | c.1744G>A p.V582I | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs767161528, COSV52999977; called by muse, mutect2, varscan2
- SLC17A8 | c.1187-1G>A p.X396_splice | Splice Site (SNP) | VAF 164/503 reads (33%) | catalogued as COSV60123474; called by muse, mutect2, varscan2
- SPAM1 | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as rs771887753, COSV56143057; called by muse, mutect2, varscan2
- TLR8 | c.596C>T p.T199M (on ENST00000218032 / NM_138636.5; = p.T217M on NM_016610.4) | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.356); catalogued as rs976964102, COSV54317525; called by muse, mutect2, varscan2
- ZNF558 | c.1169A>G p.Y390C | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.753); catalogued as rs782253032, COSV56862998; called by muse, mutect2, varscan2
- SBF2 | c.4373G>C p.S1458T | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.065); called by muse, mutect2
- DERL1 | c.705C>T p.G235= | Silent (SNP) | VAF 135/368 reads (37%) | catalogued as rs778081614, COSV52364706; called by muse, mutect2, varscan2
- EPB41L3 | c.144C>T p.F48= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs374406358, COSV59451205; called by muse, mutect2, varscan2
